Somatic mutation profile of tumor specimen 5a84eae1-197e-4463-ad65-59becc (aliquot CPT0052170010) from CPTAC case 11LU022, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 53.0 years (19,370 days).
Specimen 5a84eae1-197e-4463-ad65-59becc: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d478e504-a423-4c1f-8455-7946f02f6c9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a55e011d-f91f-4dbd-98e1-328e05 (Blood Derived Normal), aliquot CPT0038140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49c4d3e5-acd7-4690-b141-797ff60126be

The open-access MAF lists 1,226 somatic variants for this specimen: 856 protein-altering or splice-affecting, 227 silent, 143 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 721, Silent 227, Nonsense Mutation 66, Intron 60, RNA 26, Frame Shift Del 24, Splice Site 22, 5'UTR 19, 3'UTR 17, Splice Region 14, 5'Flank 13, 3'Flank 8.

Variants (750 of 1,226; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 192/411 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PKD1 | c.1583A>G p.Y528C | Missense Mutation (SNP) | VAF 60/454 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750798165, CM074432; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882028, CM134054, COSV52820679; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 58/367 reads (16%) | catalogued as COSV100741774; called by muse, mutect2, varscan2
- ABCA1 | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 56/148 reads (38%) | catalogued as COSV66066199; called by muse, mutect2, varscan2
- ABLIM1 | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV53308054; called by muse, mutect2, varscan2
- ACSF2 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771199340; called by muse, mutect2
- ACTL7B | c.189C>A p.C63* | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | catalogued as rs770078766, COSV65927703; called by muse, mutect2, varscan2
- ACTN2 | c.2671G>T p.E891* | Nonsense Mutation (SNP) | VAF 108/699 reads (15%) | catalogued as rs1177830945; called by muse, mutect2, varscan2
- ADAMTS12 | c.2703C>A p.H901Q | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs754083071, COSV61265427; called by muse, mutect2, varscan2
- ADAMTS12 | c.749C>A p.T250K | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100710838; called by muse, mutect2, varscan2
- ADGRB3 | c.967G>C p.G323R | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754128610, COSV101000771, COSV65415525; called by muse, mutect2, varscan2
- ADGRG4 | c.4447G>T p.D1483Y | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54953975, COSV54964949; called by muse, mutect2, varscan2
- ADGRL4 | c.39G>T p.L13F | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs1384447022; called by mutect2, varscan2
- AHNAK2 | c.14174C>T p.A4725V | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs763996017; called by muse, mutect2, varscan2
- AK6 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV66458692; called by muse, mutect2, varscan2
- AKNAD1 | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs751659468, COSV62200945; called by muse, mutect2, varscan2
- AKT1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV62574529; called by muse, mutect2, varscan2
- ALG10 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as rs1392426447; called by muse, mutect2, varscan2
- APOBR | c.2805G>T p.R935S (on ENST00000431282; = p.R944S on NM_018690.4) | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV60494884; called by muse, mutect2, varscan2
- APOE | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 84/386 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52985312; called by muse, mutect2, varscan2
- AQP6 | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100210145; called by muse, mutect2, varscan2
- ARHGEF10 | c.4031A>G p.H1344R (on ENST00000398564; = p.H1319R on NM_014629.4) | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs964562383; called by muse, mutect2
- ARL2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs372463350; called by muse, mutect2
- ARL3 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV53299301; called by muse, mutect2, varscan2
- ASPM | c.6392A>T p.Q2131L | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.119); catalogued as COSV54127346; called by muse, mutect2, varscan2
- ASTN2 | c.2674G>A p.E892K (on ENST00000313400 / NM_001365069.1; = p.E841K on NM_014010.5) | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV57775906; called by muse, mutect2, varscan2
- ATG16L1 | c.564G>C p.Q188H | Missense Mutation (SNP) | VAF 84/423 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779877833; called by muse, varscan2
- ATP10B | c.1732T>A p.S578T | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs1165753644; called by muse, mutect2, varscan2
- BAHCC1 | c.4416C>A p.D1472E | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV57030102; called by muse, mutect2
- C10orf71 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV60505962; called by muse, mutect2, varscan2
- C11orf87 | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV59357783; called by muse, mutect2, varscan2
- C12orf50 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1439582496, COSV100072214; called by muse, mutect2, varscan2
- CACNA1B | c.3871C>T p.L1291F | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as COSV53151838; called by muse, mutect2, varscan2
- CACNA2D2 | c.2372G>T p.R791L (on ENST00000479441 / NM_001174051.3; = p.R784L on NM_006030.4) | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99817648; called by muse, mutect2, varscan2
- CASR | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as rs1287075426, COSV56139780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC73 | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 54/393 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100813701; called by muse, mutect2, varscan2
- CDH13 | c.575A>T p.E192V | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV51871804; called by muse, mutect2, varscan2
- CDR2L | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV61501838; called by muse, mutect2, varscan2
- CERKL | c.1304G>T p.C435F (on ENST00000339098 / NM_001030311.2; = p.C409F on NM_201548.5) | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as rs778776805; called by muse, mutect2, varscan2
- CFHR4 | c.716G>T p.C239F (on ENST00000367416 / NM_001201551.2; = p.C240F on NM_001201550.3) | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99054625; called by muse, mutect2
- CHGB | c.1422C>A p.Y474* | Nonsense Mutation (SNP) | VAF 30/108 reads (28%) | catalogued as COSV66760714; called by muse, mutect2, varscan2
- CHIT1 | c.1236del p.S413Afs*65 | Frame Shift Del (DEL) | VAF 79/424 reads (19%) | catalogued as COSV55146665; called by mutect2, pindel, varscan2
- CLCA4 | c.2333G>A p.G778E | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385680044; called by muse, mutect2, varscan2
- CLHC1 | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV68464937; called by muse, mutect2
- CLVS1 | c.258C>G p.H86Q | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57980625; called by muse, mutect2, varscan2
- CMTM1 | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV50451591; called by muse, mutect2, varscan2
- CMYA5 | c.9578A>G p.Y3193C | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs755050712; called by muse, mutect2, varscan2
- CNTNAP5 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373323066; called by muse, mutect2, varscan2
- COL22A1 | c.1494G>T p.K498N | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100275485; called by muse, mutect2, varscan2
- COP1 | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as COSV58176021; called by muse, mutect2
- CR1 | c.5426G>T p.R1809I | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV100887972; called by muse, mutect2, varscan2
- CRACR2A | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs201641139; called by muse, mutect2, varscan2
- CRIM1 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 109/467 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54867848; called by muse, mutect2, varscan2
- CSMD1 | c.8797C>A p.L2933I (on ENST00000520002; = p.L2932I on NM_033225.6) | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.906); catalogued as COSV59278750; called by muse, mutect2
- CSMD1 | c.8044G>T p.G2682C (on ENST00000520002; = p.G2681C on NM_033225.6) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59338295; called by muse, mutect2
- CSMD3 | c.4190C>G p.T1397R (on ENST00000297405 / NM_001363185.1; = p.T1293R on NM_052900.3) | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as rs1456383212, COSV99837828; called by muse, mutect2, varscan2
- CSMD3 | c.4069C>T p.P1357S (on ENST00000297405 / NM_001363185.1; = p.P1253S on NM_052900.3) | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52108152; called by muse, mutect2
- CSMD3 | c.2183C>G p.P728R (on ENST00000297405 / NM_001363185.1; = p.P624R on NM_052900.3) | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV99033707; called by muse, mutect2
- CTTNBP2 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50390708; called by muse, mutect2, varscan2
- CUBN | c.4907G>T p.R1636L | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs538984401; called by muse, mutect2
- CYP2C18 | c.1284del p.S429Qfs*21 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | catalogued as COSV53674753; called by mutect2, pindel, varscan2
- DCC | c.1865C>G p.P622R | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59110301; called by muse, mutect2, varscan2
- DCSTAMP | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV52580253; called by muse, mutect2, varscan2
- DCX | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs761941490; called by muse, mutect2, varscan2
- DDR2 | c.1892G>T p.R631L | Missense Mutation (SNP) | VAF 123/444 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779963287, COSV63370061; called by muse, mutect2, varscan2
- DDX60 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs754967893, COSV101190566; called by muse, mutect2, varscan2
- DGKB | c.1838+1G>T p.X613_splice | Splice Site (SNP) | VAF 24/94 reads (26%) | catalogued as rs1211622866; called by muse, mutect2, varscan2
- DISP1 | c.2731G>T p.G911W | Missense Mutation (SNP) | VAF 107/230 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52661642; called by muse, mutect2, varscan2
- DLL3 | c.1772T>A p.L591H | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52694505; called by muse, mutect2, varscan2
- DMTN | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs1464049702, COSV56113765, COSV56114644; called by muse, mutect2, varscan2
- DNHD1 | c.8275G>A p.G2759R | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1265672341; called by muse, mutect2, varscan2
- DOCK2 | c.3339C>A p.D1113E | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV56955974; called by muse, mutect2, varscan2
- EGFL6 | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 45/107 reads (42%) | catalogued as COSV63632913; called by muse, mutect2, varscan2
- ELMO1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215535046, COSV60319959; called by muse, mutect2
- ERO1B | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1451885222; called by muse, mutect2, varscan2
- ESRRG | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 41/442 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63184975; called by muse, mutect2
- F2R | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 88/430 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV100058748; called by muse, mutect2, varscan2
- FAM184A | c.803G>T p.R268M | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58857687; called by muse, varscan2
- FBH1 | c.136A>T p.R46* (on ENST00000362091 / NM_178150.3; = p.R97* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV62982431; called by muse, mutect2, varscan2
- FBXL13 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1305424026; called by muse, mutect2, varscan2
- FCRL5 | c.716G>C p.W239S | Missense Mutation (SNP) | VAF 154/601 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.243); catalogued as COSV100708780; called by muse, mutect2, varscan2
- FHOD3 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs373907940; called by muse, mutect2, varscan2
- FIBIN | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); catalogued as COSV100590475; called by muse, mutect2, varscan2
- FLT3 | c.2005G>T p.G669* | Nonsense Mutation (SNP) | VAF 42/163 reads (26%) | catalogued as COSV54074688; called by muse, mutect2, varscan2
- FMN2 | c.2585del p.P862Lfs*25 | Frame Shift Del (DEL) | VAF 26/238 reads (11%) | catalogued as COSV100144697; called by mutect2, pindel
- FNDC1 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs562863779, COSV51937507; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1354668667, COSV58546290; called by muse, mutect2, varscan2
- FZD2 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV59529835; called by muse, mutect2, varscan2
- GABRD | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs759836961; called by muse, mutect2, varscan2
- GCN1 | c.6340C>G p.P2114A | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV56113602; called by muse, mutect2, varscan2
- GIMAP8 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56234520; called by muse, mutect2, varscan2
- GRIA4 | c.2399C>A p.S800Y | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV99233315; called by muse, mutect2, varscan2
- GRID2 | c.2902A>G p.R968G | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1005565139; called by muse, mutect2, varscan2
- GRID2 | c.2903G>A p.R968K | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as COSV99948588; called by muse, mutect2, varscan2
- GRIN2B | c.905C>A p.T302N | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.92); catalogued as rs1321033549, COSV74206894, COSV74207228; called by muse, mutect2, varscan2
- GRM6 | c.1081T>A p.W361R | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51448607; called by muse, mutect2, varscan2
- GRM7 | c.837C>A p.N279K | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV63174841; called by muse, mutect2, varscan2
- HBB | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs33949930, CM930365; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- HCN1 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs775543627, COSV57495256; called by muse, mutect2, varscan2
- HCRTR2 | c.667T>A p.Y223N | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV63795124; called by muse, mutect2, varscan2
- HHLA2 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 103/233 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs778938592; called by muse, mutect2, varscan2
- HMCN2 | c.9205G>T p.E3069* | Nonsense Mutation (SNP) | VAF 50/354 reads (14%) | catalogued as rs571592638; called by muse, mutect2, varscan2
- HRNR | c.1312A>T p.S438C | Missense Mutation (SNP) | VAF 120/533 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.712); catalogued as COSV64257754; called by muse, mutect2, varscan2
- HSD17B4 | c.1858G>T p.D620Y (on ENST00000414835 / NM_001199291.3; = p.D595Y on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV56339928; called by muse, varscan2
- HTR5A | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV55288351; called by muse, mutect2, varscan2
- HTR5A | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV55281263; called by muse, mutect2, varscan2
- HYPK | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1440063953, COSV51039229; called by muse, mutect2, varscan2
- IGKV1D-17 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 68/804 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1257952822; called by muse, mutect2
- IGSF8 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 31/93 reads (33%) | catalogued as rs746322082; called by muse, mutect2, varscan2
- IL17A | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV100391559; called by muse, mutect2, varscan2
- ILDR2 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 91/606 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs765518152, COSV54829316; called by muse, mutect2, varscan2
- IMP3 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 23/179 reads (13%) | catalogued as rs1196025013; called by muse, mutect2, varscan2
- INHBA | c.805G>T p.G269W | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54226444; called by muse, varscan2
- IPO5 | c.1424A>G p.K475R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs752929201; called by muse, mutect2, varscan2
- ITGAD | c.3467C>A p.P1156Q | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as COSV54932339; called by muse, mutect2, varscan2
- ITGAX | c.361T>A p.Y121N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99191914; called by muse, mutect2, varscan2
- ITGAX | c.2942C>A p.A981D | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.867); catalogued as rs368430021; called by muse, mutect2, varscan2
- ITPR3 | c.4448C>T p.P1483L | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV65408171; called by muse, mutect2, varscan2
- KATNIP | c.4435A>G p.I1479V | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.355); catalogued as COSV55191760; called by muse, mutect2, varscan2
- KCNA5 | c.1485C>G p.I495M | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.896); catalogued as COSV52906566, COSV52907574; called by muse, mutect2, varscan2
- KCNC4 | c.1475G>C p.R492P | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100873629; called by muse, varscan2
- KCNK2 | c.116C>T p.T39M (on ENST00000444842 / NM_001017425.3; = p.T24M on NM_014217.4) | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV67206203; called by muse, mutect2, varscan2
- KCNU1 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs935928517, COSV67755967; called by muse, varscan2
- KIAA1217 | c.2995A>G p.M999V | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs957053253; called by muse, mutect2
- KIF19 | c.1007C>A p.T336N | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63429377; called by muse, varscan2
- KLK8 | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51594309; called by muse, mutect2, varscan2
- KRT73 | c.630C>G p.S210R | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV59838771; called by muse, mutect2, varscan2
- KRTAP13-4 | c.381C>A p.Y127* | Nonsense Mutation (SNP) | VAF 32/127 reads (25%) | catalogued as COSV61879006; called by muse, mutect2, varscan2
- KRTAP16-1 | c.1524G>T p.Q508H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.788); catalogued as rs1489250395, COSV66939109; called by muse, varscan2
- LCE1E | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64219665; called by muse, mutect2, varscan2
- LCE3A | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 74/471 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV59550310; called by muse, mutect2, varscan2
- LEKR1 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV100739451; called by muse, mutect2, varscan2
- LMX1A | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs573161821; called by muse, mutect2, varscan2
- LRBA | c.6641G>T p.R2214L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs771140734, COSV100841470; called by muse, mutect2, varscan2
- LRFN5 | c.455T>A p.L152Q | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99982872; called by muse, mutect2, varscan2
- LRRC52 | c.867del p.T290Lfs*60 | Frame Shift Del (DEL) | VAF 126/401 reads (31%) | catalogued as COSV104399619; called by mutect2, pindel, varscan2
- LRRIQ1 | c.4921del p.V1641Ffs*10 | Frame Shift Del (DEL) | VAF 44/184 reads (24%) | catalogued as COSV67836237; called by mutect2, pindel, varscan2
- MARS2 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 89/384 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV56572120; called by muse, mutect2, varscan2
- MC3R | c.16T>A p.C6S | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV54764865; called by muse, mutect2, varscan2
- MDH1B | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs149261165; called by mutect2, varscan2
- MEGF9 | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64236363; called by muse, mutect2
- MGAM | c.1849G>T p.G617C | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074989; called by muse, mutect2, varscan2
- MLLT6 | c.2157C>T p.I719= | Splice Region (SNP) | VAF 29/160 reads (18%) | catalogued as rs1200602204; called by muse, mutect2, varscan2
- MMP3 | c.289G>T p.V97F | Missense Mutation (SNP) | VAF 86/245 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs547601378; called by muse, mutect2, varscan2
- MPC2 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV99607487; called by muse, mutect2
- MROH9 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1388589038; called by muse, mutect2, varscan2
- MTNR1B | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 116/294 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57065762; called by muse, mutect2, varscan2
- MUC12 | c.12607C>G p.H4203D (on ENST00000379442; = p.H4060D on NM_001164462.1) | Missense Mutation (SNP) | VAF 135/926 reads (15%) | SIFT tolerated (0.33); catalogued as COSV65210144; called by muse, mutect2, varscan2
- MUC16 | c.38452C>A p.H12818N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as rs267605781, COSV67464928; called by muse, mutect2, varscan2
- MUC7 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 59/342 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV59220355; called by muse, varscan2
- MXRA5 | c.4661G>A p.G1554E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1394728357; called by muse, mutect2, varscan2
- MYCBP2 | c.10606A>T p.M3536L (on ENST00000357337; = p.M3574L on NM_015057.5) | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.354); catalogued as COSV62019012; called by muse, mutect2, varscan2
- MYMK | c.184C>A p.R62S | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.23); catalogued as rs758679039, CM1412556, COSV60601205; called by muse, mutect2, varscan2
- MYT1 | c.2675+4C>A | Splice Region (SNP) | VAF 100/225 reads (44%) | catalogued as rs780792496; called by muse, mutect2, varscan2
- NBEA | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.367); catalogued as COSV100080547; called by muse, mutect2, varscan2
- NCOR1 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51963704, COSV99251193; called by muse, mutect2, varscan2
- NF1 | c.6225G>T p.W2075C (on ENST00000358273 / NM_001042492.3; = p.W2054C on NM_000267.3) | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62207108; called by muse, mutect2, varscan2
- NF1 | c.6675G>T p.W2225C (on ENST00000358273 / NM_001042492.3; = p.W2204C on NM_000267.3) | Missense Mutation (SNP) | VAF 96/338 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1411402, COSV62224628; called by mutect2, varscan2
- NFKB1 | c.1491G>C p.Q497H (on ENST00000394820 / NM_001382627.1; = p.Q498H on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs751909408, COSV56960081; called by muse, mutect2, varscan2
- NLRC3 | c.1522G>A p.G508R | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.32); catalogued as rs773631921, COSV57089007; called by muse, mutect2, varscan2
- NPAP1 | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.679); catalogued as COSV100276023; called by muse, mutect2, varscan2
- NPSR1 | c.1023C>A p.C341* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | catalogued as rs1055134265; called by muse, varscan2
- NRG2 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV56839357; called by muse, mutect2, varscan2
- NTRK3 | c.1160C>A p.A387D | Missense Mutation (SNP) | VAF 69/305 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs752786275, COSV58142505; called by muse, mutect2, varscan2
- NYX | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as CP005303; called by muse, mutect2, varscan2
- OPRK1 | c.447G>T p.L149F | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55569008; called by muse, mutect2, varscan2
- OR10C1 | c.802G>T p.D268Y (on ENST00000622521; = p.D266Y on NM_013941.3) | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV65822153, COSV65822361; called by muse, mutect2
- OR2L13 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.491); catalogued as COSV63549629; called by muse, varscan2
- OR2T1 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822237, COSV63541456; called by muse, mutect2
- OR2T1 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63541677; called by muse, mutect2
- OR2T10 | c.756T>A p.Y252* | Nonsense Mutation (SNP) | VAF 49/119 reads (41%) | catalogued as COSV100393598; called by muse, mutect2, varscan2
- OR2T10 | c.437C>A p.S146* | Nonsense Mutation (SNP) | VAF 42/453 reads (9%) | catalogued as COSV57897670; called by muse, mutect2
- OR2T27 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 66/453 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.479); catalogued as COSV100788083; called by muse, mutect2, varscan2
- OR4N2 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 60/405 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60049800; called by muse, mutect2, varscan2
- OR51B6 | c.344C>G p.A115G | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100970888; called by muse, mutect2
- OR51V1 | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV58315628; called by muse, mutect2, varscan2
- OR5M11 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs371385033, COSV73142046; called by muse, mutect2, varscan2
- OR6F1 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs750201701; called by muse, mutect2
- PAPPA2 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 110/347 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as COSV62777306, COSV62784565; called by muse, mutect2, varscan2
- PBX2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV66709114; called by muse, mutect2, varscan2
- PCARE | c.3176C>T p.P1059L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV59053876; called by muse, varscan2
- PCDH15 | c.4777C>G p.P1593A (on ENST00000644397 / NM_001354429.2; = p.P1535A on NM_001142771.2) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.063); catalogued as COSV64712250; called by muse, mutect2
- PCDH15 | c.4923G>T p.E1641D | Missense Mutation (SNP) | VAF 49/350 reads (14%) | SIFT tolerated, low confidence (0.16); catalogued as COSV64739703; called by muse, mutect2, varscan2
- PCDH7 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.605); catalogued as COSV100688827; called by muse, mutect2, varscan2
- PCDHA2 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs782431271, COSV65371788; called by muse, mutect2, varscan2
- PCDHB9 | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 76/648 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1554283271, COSV53383122; called by muse, mutect2, varscan2
- PCDHGB4 | c.2004G>T p.E668D | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.212); catalogued as COSV54035723; called by muse, mutect2, varscan2
- PCNX3 | c.5759G>T p.R1920L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.022); catalogued as rs376689715; called by muse, mutect2, varscan2
- PDE4B | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV58475585; called by muse, mutect2, varscan2
- PEG3 | c.3163C>T p.Q1055* | Nonsense Mutation (SNP) | VAF 46/131 reads (35%) | catalogued as COSV55636987; called by muse, mutect2, varscan2
- PEG3 | c.907G>T p.G303W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55645979; called by muse, mutect2, varscan2
- PHF21B | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100504099; called by muse, mutect2, varscan2
- PICK1 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 59/218 reads (27%) | catalogued as COSV63660060; called by muse, mutect2, varscan2
- PKD1 | c.2338G>T p.V780L | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs780727251; called by muse, mutect2, varscan2
- PLG | c.2249C>A p.A750D | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV57513424; called by muse, mutect2, varscan2
- PNPLA8 | c.1441G>T p.G481C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99993338; called by muse, mutect2, varscan2
- POM121L12 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.025); catalogued as rs202031574, COSV68692498; called by muse, mutect2, varscan2
- POSTN | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.111); catalogued as rs996691431, COSV65712979; called by muse, mutect2, varscan2
- POTEC | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 72/587 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV62800647; called by muse, mutect2, varscan2
- PREX1 | c.4406C>T p.T1469M | Missense Mutation (SNP) | VAF 114/359 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs558809203, COSV64253097; called by muse, mutect2, varscan2
- PRR30 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 23/142 reads (16%) | catalogued as rs371357819; called by muse, mutect2, varscan2
- PSG11 | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV60453405; called by muse, mutect2, varscan2
- PTPN5 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 21/168 reads (13%) | catalogued as COSV100659604; called by muse, mutect2, varscan2
- PTPRN | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs910099933, COSV55352210; called by muse, mutect2
- PTPRT | c.3345C>A p.C1115* | Nonsense Mutation (SNP) | VAF 28/189 reads (15%) | catalogued as COSV61973002; called by muse, mutect2, varscan2
- PYGL | c.1404-1G>T p.X468_splice | Splice Site (SNP) | VAF 89/407 reads (22%) | catalogued as COSV99368288; called by muse, mutect2, varscan2
- RASSF2 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101040712; called by muse, mutect2, varscan2
- RB1 | c.1695+1G>T p.X565_splice | Splice Site (SNP) | VAF 30/120 reads (25%) | catalogued as CS051701, CS146442, COSV57297353, COSV57300949, COSV99925943; called by muse, mutect2, varscan2
- RFX6 | c.2575A>G p.T859A | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1562150034; called by muse, mutect2, varscan2
- ROBO4 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 38/136 reads (28%) | catalogued as rs1021738514; called by muse, mutect2, varscan2
- RUNX1T1 | c.1282G>C p.A428P (on ENST00000265814 / NM_001198628.1; = p.A401P on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56153400; called by muse, mutect2, varscan2
- RYR2 | c.7159G>T p.A2387S | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as CM056386, HM030024, COSV100770091; called by muse, mutect2, varscan2
- SALL3 | c.3296C>A p.A1099E | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs752632478, COSV101610077, COSV73306079; called by muse, mutect2, varscan2
- SEC14L3 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99307179; called by muse, mutect2, varscan2
- SEMA5A | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV101227727, COSV101228693; called by muse, mutect2
- SFMBT2 | c.2081G>T p.R694L | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100738725; called by muse, mutect2, varscan2
- SLAIN2 | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV51903869; called by muse, mutect2
- SLC22A6 | c.584C>A p.S195* | Nonsense Mutation (SNP) | VAF 31/232 reads (13%) | catalogued as COSV64560006; called by muse, mutect2, varscan2
- SLC24A2 | c.1259C>A p.T420K | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs772147523; called by muse, mutect2, varscan2
- SLC4A9 | c.1679G>T p.G560V (on ENST00000507527 / NM_001258428.2; = p.G536V on NM_031467.3) | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.944); catalogued as rs1348118876; called by muse, mutect2, varscan2
- SLC6A16 | c.457G>T p.G153W | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60027599, COSV60027711; called by muse, mutect2, varscan2
- SLIT3 | c.2771C>A p.P924Q | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60596867, COSV60603101; called by muse, mutect2, varscan2
- SNX10 | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs746225375; called by muse, mutect2, varscan2
- SNX8 | c.1284+1G>T p.X428_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | catalogued as COSV56125412; called by muse, mutect2, varscan2
- SPANXN2 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 71/474 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV65127843, COSV65127901; called by muse, varscan2
- SPHKAP | c.2870C>A p.P957H | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290711551; called by muse, mutect2, varscan2
- SPOCK3 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100692962; called by muse, mutect2, varscan2
- SPOCK3 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.203); catalogued as rs1197016635; called by muse, mutect2, varscan2
- SPTBN1 | c.6025C>T p.R2009* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as COSV100441993, COSV61694671; called by muse, mutect2
- SRCAP | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs749992209; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.527A>T p.Y176F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | PolyPhen probably damaging (0.909); catalogued as COSV100603046; called by muse, mutect2, varscan2
- STRN3 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); catalogued as rs754971964; called by muse, varscan2
- SYNE2 | c.9236G>T p.S3079I | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV59964049; called by muse, mutect2, varscan2
- TACC2 | c.4604G>T p.G1535V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV100551826; called by muse, mutect2, varscan2
- TBC1D30 | c.1853G>T p.R618L (on ENST00000542120; = p.R455L on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV57487274; called by muse, mutect2, varscan2
- TG | c.7754+1G>T p.X2585_splice | Splice Site (SNP) | VAF 50/171 reads (29%) | catalogued as COSV55077076; called by muse, mutect2, varscan2
- THBS4 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63470135; called by muse, mutect2, varscan2
- TICRR | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV51540387; called by muse, mutect2, varscan2
- TIMELESS | c.2988G>T p.Q996H | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV57510821; called by muse, mutect2, varscan2
- TMEM109 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV50000509, COSV50001794, COSV99134195; called by muse, mutect2, varscan2
- TMEM131 | c.3119C>T p.S1040L | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs928111211; called by muse, mutect2
- TNFRSF11B | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV52069698; called by muse, mutect2
- TNR | c.1688C>A p.A563D | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.952); catalogued as COSV54869230, COSV54922353; called by muse, mutect2, varscan2
- TPO | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 95/480 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61096542; called by muse, mutect2, varscan2
- TPR | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs768820753, COSV100824279; called by muse, mutect2, varscan2
- TRIM31 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 122/321 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs750812506; called by muse, mutect2, varscan2
- TRPM1 | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 109/394 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99856336; called by muse, mutect2, varscan2
- TRPV5 | c.842C>A p.T281K | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99520758; called by muse, mutect2, varscan2
- TUBA3E | c.526del p.Q176Rfs*14 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | catalogued as rs773112295; called by mutect2, varscan2
- TUBAL3 | c.398C>A p.A133E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as rs370277463; called by muse, varscan2
- TUT7 | c.4108C>T p.R1370* | Nonsense Mutation (SNP) | VAF 9/116 reads (8%) | catalogued as rs1277431098; called by muse, mutect2
- UBA6 | c.1835A>G p.N612S | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375131806; called by muse, mutect2, varscan2
- UCN2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.368); catalogued as rs773846274, COSV99866364; called by muse, mutect2, varscan2
- UNC80 | c.9205C>A p.R3069S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV99779542; called by muse, mutect2, varscan2
- USP35 | c.2777G>T p.R926L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as rs771087419, COSV60867149; called by muse, mutect2, varscan2
- VRTN | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs754770535; called by muse, mutect2, varscan2
- WWP1 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs267602027, COSV55357876; called by muse, mutect2, varscan2
- XKR4 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs745961938, COSV59312652; called by muse, mutect2, varscan2
- XYLT1 | c.1883del p.R628Pfs*17 | Frame Shift Del (DEL) | VAF 56/337 reads (17%) | catalogued as COSV54497836; called by mutect2, pindel, varscan2
- ZBTB49 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.343); catalogued as rs140280813; called by muse, mutect2, varscan2
- ZDBF2 | c.6290C>A p.A2097D | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.658); catalogued as rs1016259008; called by muse, mutect2, varscan2
- ZFR2 | c.972C>A p.C324* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | catalogued as COSV99507699; called by muse, mutect2, varscan2
- ZNF331 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389101605; called by muse, mutect2, varscan2
- ZNF667 | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV52634760; called by muse, mutect2, varscan2
- ZNF727 | c.935A>G p.Y312C | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1294599184, COSV101407106; called by muse, mutect2, varscan2
- ZNF793 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750725429; called by muse, mutect2
- ZNF804A | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100166002; called by muse, mutect2, varscan2
- ZNF804A | c.2889G>T p.Q963H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56469084; called by muse, mutect2, varscan2
- ZSCAN10 | c.1312C>A p.R438S (on ENST00000252463; = p.R493S on NM_032805.3) | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as rs1203475459, COSV52969639; called by muse, mutect2, varscan2
- ABCA13 | c.6281T>C p.L2094P | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AC245033.1 | c.1454A>T p.E485V | Missense Mutation (SNP) | VAF 199/864 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ACAN | c.467A>T p.H156L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAN | c.7280G>T p.R2427L (on ENST00000560601 / NM_001369268.1; = p.R2351L on NM_001135.3) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ADAM19 | c.2606G>T p.G869V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ADAMTS16 | c.1652A>T p.E551V | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ADAMTS5 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1618T>C p.W540R | Missense Mutation (SNP) | VAF 107/309 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY2 | c.2361C>A p.D787E | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY3 | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRL2 | c.2342A>G p.D781G (on ENST00000370717 / NM_001366005.1; = p.D768G on NM_012302.4) | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADGRL3 | c.3487A>T p.M1163L (on ENST00000506720 / NM_001322402.2; = p.M1095L on NM_015236.6) | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADH1B | c.625G>T p.V209F | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ADORA1 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- AFP | c.1584T>A p.D528E | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AHCY | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 48/678 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.554); called by muse, mutect2
- AK9 | c.5282G>A p.C1761Y | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- AK9 | c.4762A>T p.S1588C | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AKR7A3 | c.957G>T p.W319C | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AKR7A3 | c.956G>T p.W319L | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDOA | c.409A>G p.T137A (on ENST00000642816 / NM_001243177.4; = p.T83A on NM_184041.5) | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ALG13 | c.2134G>C p.E712Q | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ALPK1 | c.1639G>T p.V547F | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ALPK2 | c.6201G>T p.W2067C | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANHX | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- ANK2 | c.4933A>T p.N1645Y | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ANK2 | c.11305C>T p.Q3769* | Nonsense Mutation (SNP) | VAF 22/172 reads (13%) | called by muse, mutect2, varscan2
- ANXA8 | c.207+6G>T | Splice Region (SNP) | VAF 9/38 reads (24%) | called by mutect2, varscan2
- AP3B1 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 29/326 reads (9%) | called by muse, mutect2
- APBB1 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- APOL5 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ARHGAP26 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP36 | c.206A>C p.H69P | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ARID1A | c.2211G>T p.M737I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- ASB3 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, varscan2
- ASCC3 | c.5949G>T p.K1983N | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ASPM | c.3390+1G>T p.X1130_splice | Splice Site (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2, varscan2
- ASTN1 | c.3064C>A p.P1022T | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASXL3 | c.6118C>A p.P2040T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ATG14 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ATG16L1 | c.585G>T p.M195I | Missense Mutation (SNP) | VAF 84/363 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.346); called by muse, varscan2
- ATG2B | c.3425G>T p.W1142L | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATG4A | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ATP2B3 | c.2541C>A p.D847E | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ATP4A | c.601del p.L201Wfs*4 | Frame Shift Del (DEL) | VAF 27/197 reads (14%) | called by mutect2, pindel, varscan2
- ATP6V0A1 | c.647A>G p.H216R | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- ATP6V1E2 | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AXIN1 | c.2155A>C p.K719Q | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- BBOX1 | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BEND2 | c.2170A>G p.I724V | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- BMP7 | c.192G>T p.L64F | Missense Mutation (SNP) | VAF 100/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BNC1 | c.2832G>T p.R944S | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BNC1 | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BNIPL | c.795G>T p.R265S | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- BPTF | c.1321G>C p.G441R | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRAT1 | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- BRIP1 | c.1966A>T p.K656* | Nonsense Mutation (SNP) | VAF 44/309 reads (14%) | called by muse, mutect2, varscan2
- BTF3 | c.235A>T p.R79* (on ENST00000380591 / NM_001037637.1; = p.R35* on NM_001207.4) | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- BTN2A1 | c.713-6_739del p.X238_splice | Splice Site (DEL) | VAF 14/166 reads (8%) | called by mutect2, pindel
- C12orf66 | c.1001A>T p.H334L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf46 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | called by muse, mutect2, varscan2
- C19orf84 | c.351G>T p.W117C | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- C3orf14 | c.4A>G p.T2A | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CACNA1G | c.5549T>C p.L1850P | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CACNA1S | c.1664C>A p.S555Y | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1S | c.1470G>T p.Q490H | Missense Mutation (SNP) | VAF 199/504 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CACNG8 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CALHM4 | c.883G>A p.G295R (on ENST00000368596 / NM_001366078.1; = p.G109R on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CALR | c.780G>T p.E260D | Missense Mutation (SNP) | VAF 118/429 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CAND1 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CASP8AP2 | c.2454G>T p.Q818H | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CASP8AP2 | c.2870G>T p.R957L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASZ1 | c.380A>T p.Q127L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); called by muse, mutect2
- CATSPER1 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CATSPERE | c.1331G>T p.S444I | Missense Mutation (SNP) | VAF 149/375 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CCDC40 | c.3212G>T p.R1071L | Missense Mutation (SNP) | VAF 35/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- CCKAR | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCT8L2 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.824); called by muse, varscan2
- CCT8L2 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.065); called by muse, varscan2
- CD101 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- CD163 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CD1A | c.59-2A>T p.X20_splice | Splice Site (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2
- CD1E | c.1084C>A p.H362N | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD6 | c.1719C>A p.C573* | Nonsense Mutation (SNP) | VAF 61/481 reads (13%) | called by muse, mutect2, varscan2
- CDH12 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CDH23 | c.146-1G>T p.X49_splice | Splice Site (SNP) | VAF 24/210 reads (11%) | called by muse, mutect2, varscan2
- CDK8 | c.456G>T p.L152F | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CDKL2 | c.1430C>A p.P477H | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- CDRT15L2 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CEBPB | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 299/862 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEL | c.14G>T p.G5V (on ENST00000673714; = p.G2V on NM_001807.6) | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CELSR1 | c.5522T>A p.M1841K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2
- CEP192 | c.2771G>T p.C924F | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.116); called by muse, mutect2
- CEP350 | c.4109A>T p.K1370M | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CERS1 | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CFAP43 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHRNA1 | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 117/543 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CHRNA9 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHST3 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIDEA | c.654T>A p.C218* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- CKM | c.505T>A p.F169I | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CLDN14 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CLDN25 | c.635A>T p.E212V | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- COBLL1 | c.2011A>T p.S671C (on ENST00000392717; = p.S633C on NM_014900.5) | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- COG7 | c.1730A>T p.Q577L | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL14A1 | c.4708C>A p.P1570T | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.358); called by muse, mutect2
- COL14A1 | c.4709C>A p.P1570Q | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.223); called by muse, mutect2
- COL4A1 | c.3262G>C p.G1088R | Missense Mutation (SNP) | VAF 148/422 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A1 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 46/510 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2
- COL5A1 | c.2009G>T p.G670V | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- COP1 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRACD | c.1395G>T p.Q465H | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CRB1 | c.1610T>A p.L537Q | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CREBBP | c.6741G>T p.Q2247H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CRTC3 | c.476+1G>A p.X159_splice | Splice Site (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- CSMD1 | c.3188G>T p.G1063V (on ENST00000520002; = p.G1062V on NM_033225.6) | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL3 | c.1303C>G p.H435D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CXCL1 | c.164A>T p.K55M | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYFIP2 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CYP2W1 | c.489C>A p.G163= | Splice Region (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- CYP3A5 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CYYR1 | c.108_113del p.K36_Y38delinsN | In Frame Del (DEL) | VAF 23/104 reads (22%) | called by mutect2, pindel, varscan2
- DBX2 | c.915G>T p.E305D | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- DCUN1D4 | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DDX60 | c.4196C>T p.S1399F | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- DDX60L | c.4+2T>A p.X2_splice | Splice Site (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- DEFB113 | c.127A>T p.K43* | Nonsense Mutation (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- DENND5B | c.1688A>T p.E563V | Missense Mutation (SNP) | VAF 125/276 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND5B | c.1687G>T p.E563* | Nonsense Mutation (SNP) | VAF 126/274 reads (46%) | called by muse, mutect2, varscan2
- DGAT2L6 | c.749dup p.D251Gfs*47 | Frame Shift Ins (INS) | VAF 133/261 reads (51%) | called by mutect2, pindel, varscan2
- DICER1 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- DLGAP2 | c.2858A>C p.Q953P | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DMBT1 | c.2538G>T p.W846C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.916); called by mutect2, varscan2
- DNAH17 | c.3735G>T p.M1245I | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DNAH17 | c.693G>C p.W231C | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH3 | c.10694T>G p.M3565R | Missense Mutation (SNP) | VAF 37/365 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- DNAJC30 | c.535del p.E179Nfs*4 | Frame Shift Del (DEL) | VAF 39/237 reads (16%) | called by mutect2, pindel, varscan2
- DPYSL4 | c.528C>A p.C176* | Nonsense Mutation (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- DSC3 | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DSCAML1 | c.5278A>G p.T1760A (on ENST00000321322; = p.T1700A on NM_020693.4) | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DSE | c.1297A>G p.R433G | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSG2 | c.3341A>T p.Q1114L | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- DSPP | c.2498G>T p.S833I | Missense Mutation (SNP) | VAF 61/568 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); called by muse, mutect2
- DTHD1 | c.1393G>T p.G465C (on ENST00000456874; = p.G300C on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EBF3 | c.865T>C p.F289L (on ENST00000355311 / NM_001375392.1; = p.F280L on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ECEL1 | c.2055C>A p.H685Q | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- EDIL3 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- EEF1AKMT3 | c.289+1G>C p.X97_splice | Splice Site (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- ELFN1 | c.1897G>T p.A633S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ELFN2 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 53/160 reads (33%) | called by muse, mutect2, varscan2
- ELOVL6 | c.506T>C p.M169T | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ENTHD1 | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- EPB42 | c.217A>C p.N73H (on ENST00000441366 / NM_001114134.2; = p.N103H on NM_000119.3) | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by mutect2, varscan2
- EPHB3 | c.2646G>T p.R882S | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERI3 | c.770A>T p.Q257L | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- ESRRB | c.1389C>A p.S463R | Missense Mutation (SNP) | VAF 68/425 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- F9 | c.986G>C p.S329T | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM131B | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2
- FAM184A | c.804G>T p.R268S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- FAM205A | c.295T>A p.C99S | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- FAM47C | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM50A | c.52A>T p.M18L | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- FAM8A1 | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM90A13P | n.323G>A | Splice Region (SNP) | VAF 13/39 reads (33%) | called by mutect2, varscan2
- FASN | c.7094C>A p.T2365K | Missense Mutation (SNP) | VAF 43/400 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FBLN7 | c.1201A>G p.N401D | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FBN3 | c.5462G>C p.C1821S | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBXL7 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 38/640 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.153); called by muse, mutect2
- FCGR2C | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 73/540 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FCRL3 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FES | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 36/128 reads (28%) | called by muse, mutect2, varscan2
- FFAR1 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FGF2 | c.48del p.G17Afs*37 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- FNBP1 | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.24); called by muse, varscan2
- FNDC1 | c.3458G>T p.R1153M | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.068); called by muse, mutect2
- FOCAD | c.307A>T p.K103* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | called by mutect2, varscan2
- FOXD3 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FRMD4A | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FSHB | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- FUBP3 | c.1291G>T p.G431* | Nonsense Mutation (SNP) | VAF 14/171 reads (8%) | called by muse, mutect2
- GABRA1 | c.1260C>A p.D420E | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRE | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- GADL1 | c.606G>T p.K202N | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GALR1 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- GAS1 | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- GATAD2A | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, varscan2
- GBE1 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- GCK | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCM1 | c.455A>G p.H152R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GFRA1 | c.1196A>G p.Q399R | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by muse, varscan2
- GFRA1 | c.1195C>A p.Q399K | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GHDC | c.497G>A p.W166* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- GLDC | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GLDC | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- GLIS1 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 54/130 reads (42%) | called by muse, mutect2, varscan2
- GNS | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GP9 | c.79C>A p.R27S | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GPR78 | c.496C>G p.R166G | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPR85 | c.921G>A p.W307* | Nonsense Mutation (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- GPRC6A | c.2034G>T p.L678F | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- GRIK4 | c.1057A>T p.M353L | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRM8 | c.2712C>A p.S904R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); called by muse, varscan2
- GSKIP | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.733); called by muse, varscan2
- GUCA1A | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 52/236 reads (22%) | called by muse, mutect2, varscan2
- HAS1 | c.1059C>A p.T353= | Splice Region (SNP) | VAF 20/78 reads (26%) | called by muse, varscan2
- HBS1L | c.1582A>T p.T528S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.912); called by muse, mutect2
- HCK | c.169T>A p.S57T | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HCN2 | c.2650C>A p.R884S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEATR1 | c.3723G>T p.L1241F | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- HOXC10 | c.606del p.K203Sfs*51 | Frame Shift Del (DEL) | VAF 43/146 reads (29%) | called by mutect2, pindel, varscan2
- HR | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- HS3ST5 | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HSPB8 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- HTR1A | c.399C>A p.D133E | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR1E | c.69G>T p.M23I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.12426G>T p.W4142C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.871); called by mutect2, varscan2
- ICE1 | c.386A>T p.Q129L | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); called by muse, mutect2
- IGHE | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGHMBP2 | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 76/331 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV1-27 | c.117C>A p.D39E | Missense Mutation (SNP) | VAF 56/385 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- IL10RA | c.1025C>A p.P342H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- IL18RAP | c.1656G>T p.W552C | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ING3 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, varscan2
- INSYN2B | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- INTS2 | c.3577G>T p.V1193L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, varscan2
- INTS2 | c.3279G>T p.Q1093H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ISM2 | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ISX | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ITGA8 | c.2471T>A p.I824N | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ITGB1 | c.1479A>T p.E493D | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2
- ITGB1BP2 | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 92/164 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITIH6 | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ITK | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ITPRID2 | c.1648G>T p.G550C | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ITPRID2 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KCNA6 | c.1267G>T p.V423L | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCNU1 | c.2645G>T p.G882V | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, varscan2
- KCP | c.4151C>T p.S1384F (on ENST00000620378; = p.S1508F on NM_001366122.1) | Missense Mutation (SNP) | VAF 96/459 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KCTD19 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- KIAA0319L | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0825 | c.2683G>T p.E895* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- KIAA1586 | c.1807A>T p.R603W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF1A | c.4777C>A p.L1593M (on ENST00000320389 / NM_001379639.1; = p.L1585M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21A | c.3153+1G>T p.X1051_splice (on ENST00000361418 / NM_001378440.1; = p.X1038_splice on NM_017641.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- KIF26B | c.2559C>A p.D853E | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2
- KIF26B | c.2849T>G p.L950R | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.26); called by muse, mutect2
- KIF5A | c.898A>T p.M300L | Missense Mutation (SNP) | VAF 59/514 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KIF5C | c.2371G>T p.V791L | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL4 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- KMT2A | c.9353A>G p.N3118S | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.6020A>T p.E2007V | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT15 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KRT24 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- KRT5 | c.1549G>T p.G517C | Missense Mutation (SNP) | VAF 64/373 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- KRT73 | c.946A>G p.K316E | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- KTN1 | c.3331G>T p.G1111W (on ENST00000395314 / NM_001271014.2; = p.G1082W on NM_004986.4) | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KTN1 | c.3332G>T p.G1111V (on ENST00000395314 / NM_001271014.2; = p.G1082V on NM_004986.4) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAIR1 | c.755C>G p.A252G | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- LAMA1 | c.5801C>T p.S1934L | Missense Mutation (SNP) | VAF 46/528 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- LAMA3 | c.4637C>A p.P1546H | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMC2 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 24/393 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- LARS1 | c.2471G>T p.G824V (on ENST00000394434 / NM_020117.11; = p.G797V on NM_016460.3) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- LBH | c.146A>G p.*49Wext*12 | Nonstop Mutation (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- LDHA | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDLRAD3 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LILRB1 | c.1837T>A p.Y613N (on ENST00000427581; = p.Y562N on NM_006669.6) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by muse, mutect2
- LILRB5 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 36/353 reads (10%) | called by muse, mutect2
- LIN28B | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LIPM | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIX1 | c.788del p.P263Lfs*11 | Frame Shift Del (DEL) | VAF 29/170 reads (17%) | called by mutect2, pindel, varscan2
- LMNTD1 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- LMX1A | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMX1B | c.1151G>T p.R384L (on ENST00000373474 / NM_001174147.2; = p.R377L on NM_002316.4) | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, varscan2
- LPA | c.4180C>T p.Q1394* | Nonsense Mutation (SNP) | VAF 35/184 reads (19%) | called by muse, mutect2, varscan2
- LPA | c.3220A>T p.T1074S | Missense Mutation (SNP) | VAF 57/379 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- LRP12 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.077); called by muse, varscan2
- LRP1B | c.974T>A p.L325H | Missense Mutation (SNP) | VAF 21/297 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- LRRC4C | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LRRK1 | c.2535G>T p.R845S | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- LRRTM1 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LTBP1 | c.1825A>C p.M609L (on ENST00000404816 / NM_206943.4; = p.M283L on NM_000627.4) | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LZTS2 | c.876dup p.L293Afs*11 | Frame Shift Ins (INS) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- MAGEB16 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAK | c.682T>A p.Y228N | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- MAP3K9 | c.1482G>T p.E494D | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MAP7D3 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 89/136 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAP7D3 | c.184A>G p.M62V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPKAP1 | c.1040G>T p.W347L | Missense Mutation (SNP) | VAF 17/345 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MAS1L | c.97A>T p.S33C | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MED13 | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED14 | c.795G>T p.L265F | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MEGF10 | c.2119C>A p.H707N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- MFF | c.234A>T p.Q78H | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MGAM | c.1688T>A p.L563Q | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAM2 | c.4961T>A p.L1654Q | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- MICAL3 | c.5269G>C p.D1757H | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MKNK1 | c.619T>G p.C207G | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MMRN1 | c.1825G>T p.D609Y | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MMUT | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- MRPS30 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRTFB | c.1037A>T p.K346M | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- MS4A7 | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- MSH4 | c.2548G>T p.V850L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MSI2 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTIF2 | c.1970_1974del p.K657Ifs*2 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- MTUS2 | c.3253G>T p.E1085* (on ENST00000612955 / NM_001366650.1; = p.E64* on NM_015233.6) | Nonsense Mutation (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.37137A>T p.T12379= | Splice Region (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- MUC17 | c.1535C>A p.P512Q | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MUC17 | c.7093A>C p.T2365P | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MUC19 | c.686C>A p.S229* | Nonsense Mutation (SNP) | VAF 44/198 reads (22%) | called by muse, mutect2, varscan2
- MUC2 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MUC2 | c.2409del p.D804Tfs*3 | Frame Shift Del (DEL) | VAF 37/148 reads (25%) | called by mutect2, pindel, varscan2
- MUC22 | c.4113A>T p.E1371D | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT tolerated (0.58); called by muse, mutect2, varscan2
- MUC5AC | c.415A>T p.K139* | Nonsense Mutation (SNP) | VAF 53/191 reads (28%) | called by muse, mutect2, varscan2
- MYBPC2 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MYF6 | c.380G>C p.R127T | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH1 | c.4942A>T p.R1648W | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MYH2 | c.842A>T p.K281M | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- MYH7 | c.2692C>A p.L898M | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1E | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MYO3B | c.295G>T p.G99W | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NANOGNB | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NANOS2 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- NAV3 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NAV3 | c.2380G>A p.G794R | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- NCK1 | c.201T>G p.I67M | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- NCR1 | c.456G>C p.M152I | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2
- NCSTN | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 190/593 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDST4 | c.1940+1del p.X647_splice | Splice Site (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- NEB | c.4657G>T p.D1553Y | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEK10 | c.2908C>A p.H970N | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEURL1B | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- NID2 | c.3880+2T>C p.X1294_splice | Splice Site (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- NIPBL | c.2777G>T p.S926I | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NKAPL | c.182del p.G61Afs*62 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | called by mutect2, pindel
- NLRP2 | c.915C>A p.C305* | Nonsense Mutation (SNP) | VAF 77/232 reads (33%) | called by muse, mutect2, varscan2
- NLRP5 | c.865G>T p.G289* | Nonsense Mutation (SNP) | VAF 57/185 reads (31%) | called by muse, mutect2, varscan2
- NMT2 | c.392-2A>C p.X131_splice | Splice Site (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- NOBOX | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- NOL4 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NOTCH2 | c.4078A>T p.T1360S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- NPAS3 | c.2324del p.G775Afs*35 (on ENST00000356141 / NM_001164749.2; = p.G743Afs*35 on NM_022123.3) | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | called by mutect2, pindel
- NPAT | c.1750G>T p.V584L | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NPR3 | c.383C>A p.P128Q | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR4A1 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NRCAM | c.2011G>T p.D671Y (on ENST00000379028 / NM_001371124.1; = p.D655Y on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- NTNG1 | c.1208A>G p.Y403C | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NTRK1 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 80/370 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NTSR1 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NUMA1 | c.6006+1del p.X2002_splice | Splice Site (DEL) | VAF 31/117 reads (26%) | called by mutect2, pindel, varscan2
- ODF2 | c.30C>G p.P10= | Splice Region (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- OGDHL | c.2506T>G p.F836V | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- OLFM2 | c.962C>A p.S321Y | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPLAH | c.2734G>T p.G912* | Nonsense Mutation (SNP) | VAF 49/114 reads (43%) | called by muse, mutect2, varscan2
- OPN3 | c.706del p.E236Kfs*8 | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | called by mutect2, pindel, varscan2
- OPN4 | c.952G>T p.V318L | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2
- OR10X1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR14J1 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- OR1N2 | c.342C>A p.D114E | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.685); called by muse, mutect2
- OR2C3 | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- OR5C1 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- OR5F1 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5K1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 96/207 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5L1 | c.622A>T p.S208C | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- OR5M10 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- OR8H3 | c.842T>A p.V281E | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR8I2 | c.775T>A p.L259M | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- OR8K3 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- OR9I1 | c.316A>T p.I106F | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOG | c.2246T>A p.L749Q | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- OTOGL | c.284G>T p.G95V (on ENST00000547103; = p.G86V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OXR1 | c.746C>T p.P249L (on ENST00000442977 / NM_001198532.1; = p.P248L on NM_018002.3) | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- P2RY10 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 89/146 reads (61%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- P2RY13 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 114/249 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PALD1 | c.2538C>A p.S846R | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PALLD | c.1406del p.P469Lfs*38 | Frame Shift Del (DEL) | VAF 96/402 reads (24%) | called by mutect2, pindel, varscan2
- PARD3B | c.2573A>T p.E858V (on ENST00000406610 / NM_001302769.2; = p.E789V on NM_057177.7) | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PARG | c.1789A>T p.M597L | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); called by muse, varscan2
- PARP12 | c.1682A>T p.Q561L | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PAX1 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.2); called by muse, varscan2
- PAX4 | c.926del p.P309Hfs*105 | Frame Shift Del (DEL) | VAF 54/322 reads (17%) | called by mutect2, pindel, varscan2
- PCDH15 | c.4610C>T p.A1537V | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDH15 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 45/401 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- PCDHA1 | c.2127C>A p.S709R | Missense Mutation (SNP) | VAF 92/378 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PCDHA11 | c.1433C>A p.A478E | Missense Mutation (SNP) | VAF 75/670 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB10 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PCDHGA7 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PCLO | c.7978C>T p.Q2660* | Nonsense Mutation (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- PDCD11 | c.4351G>T p.E1451* | Nonsense Mutation (SNP) | VAF 56/225 reads (25%) | called by muse, mutect2, varscan2
- PDZD2 | c.3877G>A p.G1293R | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDZRN4 | c.2537A>T p.H846L (on ENST00000402685 / NM_001164595.2; = p.H588L on NM_013377.4) | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- PEG3 | c.1423A>G p.T475A | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PER1 | c.589A>C p.M197L | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- PFKM | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PHF14 | c.2076+1G>T p.X692_splice | Splice Site (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- PHF8 | c.2401G>A p.V801M (on ENST00000357988 / NM_001184896.1; = p.V765M on NM_015107.3) | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, varscan2
- PIK3C2A | c.845A>T p.D282V | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PIK3CG | c.1458G>C p.Q486H | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PIK3R1 | c.859A>T p.I287L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R2 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIWIL1 | c.1551A>T p.K517N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PKHD1 | c.2215C>A p.P739T | Missense Mutation (SNP) | VAF 51/445 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PNPT1 | c.1074-2A>G p.X358_splice | Splice Site (SNP) | VAF 38/171 reads (22%) | called by muse, mutect2, varscan2
- POLR1A | c.4838G>T p.G1613V | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR1A | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POTEA | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POTEC | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PPFIA2 | c.1646T>C p.L549P | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PRICKLE2 | c.2282G>A p.R761H (on ENST00000295902; = p.R705H on NM_198859.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- PRKG1 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- PRRC2B | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRSS23 | c.659A>T p.Q220L | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRUNE2 | c.1007A>G p.E336G | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSG5 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- PSKH2 | c.313T>A p.C105S | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.18); called by muse, mutect2
- PTHLH | c.-21T>C | Splice Region (SNP) | VAF 115/363 reads (32%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QPRT | c.824C>A p.A275E | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2948C>A p.S983* | Nonsense Mutation (SNP) | VAF 38/456 reads (8%) | called by muse, mutect2
- RAB3IP | c.807G>T p.Q269H (on ENST00000550536 / NM_175623.4; = p.Q253H on NM_022456.5) | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.58); called by muse, mutect2
- RBPJ | c.160A>G p.K54E | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- RIF1 | c.1878C>G p.D626E | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RIMS2 | c.2711G>T p.G904V (on ENST00000666250 / NM_001348490.2; = p.G712V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS2 | c.4532A>T p.E1511V (on ENST00000666250 / NM_001348490.2; = p.E1082V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RNF144A | c.478A>G p.M160V | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF213 | c.15481_15484del p.T5161Sfs*2 | Frame Shift Del (DEL) | VAF 44/378 reads (12%) | called by mutect2, pindel, varscan2
- RSBN1L | c.1381G>T p.G461C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSBN1L | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTL1 | c.2369A>G p.N790S | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- RYR2 | c.8887T>A p.F2963I | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SAR1B | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- SARDH | c.2496-4C>A | Splice Region (SNP) | VAF 99/364 reads (27%) | called by muse, mutect2, varscan2
- SCN3A | c.1818C>A p.S606R | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SDF2L1 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEC16B | c.1082G>T p.R361I | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- SELENOI | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SEMA3A | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- SEMA4F | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SEPTIN1 | c.1079G>C p.R360P (on ENST00000321367; = p.R313P on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEPTIN9 | c.1604A>G p.Y535C (on ENST00000427177 / NM_001113491.2; = p.Y517C on NM_006640.4) | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- SERPINA3 | c.897G>C p.W299C | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD5 | c.3256G>T p.G1086* | Nonsense Mutation (SNP) | VAF 47/171 reads (27%) | called by muse, mutect2, varscan2
- SFXN4 | c.241del p.A81Rfs*23 | Frame Shift Del (DEL) | VAF 20/192 reads (10%) | called by mutect2, pindel
- SGPP1 | c.907G>T p.G303W | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH2B1 | c.1342del p.A448Hfs*95 | Frame Shift Del (DEL) | VAF 22/187 reads (12%) | called by pindel, varscan2
- SHISA7 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SIGLEC6 | c.1262A>T p.E421V | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, varscan2
- SIGLEC8 | c.1195G>T p.G399W | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SIPA1L2 | c.1888G>T p.A630S | Missense Mutation (SNP) | VAF 120/318 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, varscan2
- SLAMF1 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- SLC12A8 | c.1982G>T p.R661M | Missense Mutation (SNP) | VAF 95/182 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLC15A5 | c.1481A>T p.D494V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- SLC22A16 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC25A23 | c.1180A>T p.S394C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLC25A46 | c.284-1G>T p.X95_splice | Splice Site (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- SLC2A6 | c.111G>T p.R37S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLC38A5 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- SLC4A3 | c.2207G>T p.G736V | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC5A5 | c.1618G>T p.V540L | Missense Mutation (SNP) | VAF 109/426 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC6A7 | c.706G>C p.V236L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SLCO6A1 | c.980G>T p.C327F | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLIT2 | c.3941A>T p.N1314I | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK2 | c.2167C>A p.L723M | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.854); called by mutect2, varscan2
- SMG1 | c.5781G>T p.Q1927H | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- SNAP91 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- SNX18 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SOCS1 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOGA3 | c.344C>A p.P115Q | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2
- SOGA3 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.026); called by muse, mutect2
- SORL1 | c.4779-7_4779-1delinsTTTTTTT p.X1593_splice | Splice Site (ONP) | VAF 5/48 reads (10%) | called by mutect2*, pindel
- SPATA19 | c.8T>A p.I3N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA31D1 | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 38/387 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SPEG | c.1895A>G p.E632G | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPTBN1 | c.5165G>T p.G1722V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SRRM1 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SRRM4 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, varscan2
- SSX5 | c.523G>T p.V175L (on ENST00000347757 / NM_175723.1; = p.V216L on NM_021015.4) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- STARD8 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STEAP4 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STK11IP | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
476 further variants in this file (106 protein-altering or splice-affecting, 227 silent, 143 other) are not listed here.
